Gene-level copy-number profile of tumor specimen C3N-03888-02 from CPTAC case C3N-03888, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.8 years (21,474 days).
Specimen C3N-03888-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b038a53-6831-4734-a23c-7a880f29eb59.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03888-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/3f199ae8-a375-48b6-a4d0-ebc622ee6357

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 15,650; copy number 2: 38,480; copy number 3: 3,409; copy number 4: 564; copy number 5: 90; copy number 6: 92; copy number 7: 5; copy number 8: 60; copy number 10: 3; copy number 15: 12; copy number 25: 15.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr5:102,131,007–102,146,874, 2 genes: RNA5SP188, AC008948.1.
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr9:40,755,407–40,883,763, 4 genes: AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 277 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 10 (within-gene range 3–10): AL627309.1.
- chr1:131,025–135,895, 2 genes, copy number 10: CICP27, AL627309.6.
- chr7:92,112,153–92,836,573, 23 genes, copy number 5–6 (within-gene range 1–6): CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P.
- chr8:36,004,316–39,928,790, 91 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:39,914,229–39,920,890, 2 genes, copy number 8 (within-gene range 4–8): AC007991.2, AC007991.4.
- chr11:69,641,156–70,436,584, 27 genes, copy number 15–25: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:67,648,338–70,243,379, 63 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:70,239,114–70,242,430, 1 gene, copy number 5: AC092881.2.
- chr12:70,443,784–72,670,758, 30 genes, copy number 5–8 (within-gene range 3–8): RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35.
- chr14:49,782,083–50,831,162, 37 genes, copy number 6 (within-gene range 3–6): NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2.

Autosomal genes at a single copy (total copy number 1): 13,314. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
